TARGET case TARGET-10-PARPFF — Acute Lymphoblastic Leukemia - Phase II (TARGET-ALL-P2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3c348228-780b-5f2b-9891-5afae3a75dcd

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Age at index: 15 years; Vital status: Dead; Days to death: 1,850 days (5.1 years).

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 15.5 years (5,645 days); Year of diagnosis: 2007; Days to last follow up: 1,850 days (5.1 years).
   Treatment given: Protocol identifier: AALL0232.

Follow-up (2 entries)
- Days to follow up: 1,554 days (4.3 years); Days to first event: 1,554 days (4.3 years); First event: Relapse.
- Days to follow up: 1,850 days (5.1 years); Progression or recurrence: Yes; Progression or recurrence anatomic site: Bone marrow; Year of follow up: 2012.

Molecular and laboratory tests (laboratory values grouped by visit day)
- BCR–ABL1 fusion: Negative.
- ETV6–RUNX1 fusion (FISH): Negative.
- KMT2A rearrangement (FISH): Negative.
- Trisomy 10: Negative.
- Trisomy 4: Negative.
- Day 0: Leukocytes 96.3 ×10³/µL.
- Day 8: Bone Marrow blast count 56%; Minimal Residual Disease (Flow Cytometry) 3.5%.
- Day 15: Bone Marrow blast count 4%.
- Day 29: Bone Marrow blast count 5%; Minimal Residual Disease (Flow Cytometry) 1.3%.
- Day 43: Bone Marrow blast count 3%; Minimal Residual Disease (Flow Cytometry) 0%.
- Minimal Residual Disease (Flow Cytometry) 0%.

Biospecimens (2 samples)
- Sample TARGET-10-PARPFF-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-10-PARPFF-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_Blast_Data_20230727.xlsx, for sample TARGET-10-PARPFF-09A-01D:
- Blast %: yes many

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_II_Validation_20230727.xlsx:
- Overall Survival Time in Days: 1850
- WBC at Diagnosis: 96.3
- CNS Status at Diagnosis: CNS 1
- MRD Day 8: 3.5
- MRD Day 8 Sensitivity: 0.01
- MRD Day 29: 1.3
- MRD Day 29 Sensitivity: 0.01
- MRD Day 43: 0
- MRD End Consolidation: 0
- Bone Marrow Site of Relapse: Yes
- CNS Site of Relapse: No
- Testes Site of Relapse: No
- Other Site of Relapse: No
- ETV6 RUNX1 Fusion Status: Negative
- TRISOMY 4 10 Status: Negative
- MLL Status: Negative
- BCR ABL1 Status: Negative
- BMA Blasts Day 8: 56
- BMA Blasts Day 15: 4
- BMA Blasts Day 29: 5
- BMA Blasts Day 43: 3
- Down Syndrome: No
- DNA Index: 1
- Alternate Therapy: Chemotherapy; Transplant
- Cell of Origin: B Cell ALL
